CCDI case PBCJWL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/97acf0b6-54f7-46f1-97a3-f2d3b9510d6b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Subependymal giant cell astrocytoma: ICD-O-3 morphology code: 9384/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 6.7 years (2,455 days).

Biospecimens (2 samples)
- Sample 0DTYAT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTYB3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
